Somatic mutation profile of tumor specimen 0DPJT7 from CCDI case PBCDSP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myofibroblastic tumor, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 0.6 years (208 days).
Specimen 0DPJT7: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 810758db-22f2-4df3-9090-4ab42ad2cf14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPJSB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6820b94a-0038-4f8a-b40c-c36e95e26fb4

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT3 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 41/568 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756686272, COSV56752556; called by muse, mutect2
- GRIA4 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 48/514 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200645930, COSV56888826; called by muse, mutect2, varscan2
- TMEM132B | c.2212C>T p.Q738* | Nonsense Mutation (SNP) | VAF 26/681 reads (4%) | called by muse, mutect2
- DNAH5 | c.7473C>T p.S2491= | Silent (SNP) | VAF 17/360 reads (5%) | catalogued as rs1163482951; called by muse, mutect2
- PP2D1 | c.645G>A p.A215= | Silent (SNP) | VAF 24/426 reads (6%) | catalogued as rs994896147; called by muse, mutect2
- CTTN | c.*487G>A | 3'UTR (SNP) | VAF 25/445 reads (6%) | catalogued as COSV57235017; called by muse, mutect2
